Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4442, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4442-01A (Primary Tumor).

■
Diagnosis/diagnoses:

Subtotal gastrectomy resection material with extensive metaplasia evidently on an underlying multifocal atrophic gastritis caused by previous *H. pylori* infection, with tumor-free resection margins and with the inclusion of an ulcerated poorly differentiated adenocarcinoma or gastric carcinoma of the intestinal type, located in the antrum, with infiltration of the subserosa and without regional lymph node metastases ■ pT2b pN0 0/27).

Source: NCI Genomic Data Commons file 6a73f397-40d5-4b85-8014-42cde1682adc (TCGA-CG-4442.DFD6806A-FC11-4571-B263-2F79D57AC5F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).